Gene-level copy-number profile of tumor specimen TCGA-A5-A0R6-01A from TCGA case TCGA-A5-A0R6, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 64.2 years (23,449 days).
Specimen TCGA-A5-A0R6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.9c208bbc-f4a6-45ac-90ee-643b6e091488.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A5-A0R6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/891b6dff-ab50-47a5-b13a-817a911835fa

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 5,907; copy number 3: 21,172; copy number 4: 28,664; copy number 5: 2,174; copy number 6: 915; copy number 7: 55; copy number 8: 904; copy number 9: 12; copy number 10: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A5-A0R6-01A-11D-A102-01): tumor purity 0.46, ploidy 3.53, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 20 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:28,307,063–28,751,722, 12 genes, copy number 9: AC093690.1, RPL23AP34, FLJ31356, FOSL2, AC104695.3, AC104695.2, AC104695.1, PLB1, SNRPGP7, AC074011.1, RNA5SP89, AC092164.1.
- chr2:113,157,325–113,496,204, 8 genes, copy number 10 (within-gene range 4–10): PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
